Somatic mutation profile of tumor specimen TARGET-10-PASXMF-09A (aliquot TARGET-10-PASXMF-09A-01D) from TARGET case TARGET-10-PASXMF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.4 years (3,815 days).
Specimen TARGET-10-PASXMF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a17bd98-aac1-4f56-9b0b-47a88a555bea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASXMF-10A (Blood Derived Normal), aliquot TARGET-10-PASXMF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cbddb337-cc58-49ef-9229-c6b309234dc4

The open-access MAF lists 22 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 33/81 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AUTS2 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.99); catalogued as rs1285866758, COSV61412985, COSV61436996; called by muse, mutect2, varscan2
- BMP6 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.072); catalogued as rs577694907, COSV51663347; called by muse, mutect2, varscan2
- BTNL2 | c.653G>T p.C218F | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV66630204; called by muse, mutect2
- C8orf48 | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.783); catalogued as rs780348430, COSV52046638; called by muse, mutect2, varscan2
- CD300E | c.463C>T p.L155F | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV60792360; called by muse, mutect2, varscan2
- IMPG2 | c.2158G>T p.A720S | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs1230071793, COSV51987233; called by muse, mutect2, varscan2
- NKX3-2 | c.860G>T p.R287L | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs754533227, COSV101219830; called by muse, mutect2
- SVIP | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 69/144 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780103291, COSV62602943; called by muse, mutect2, varscan2
- WNK1 | c.2489C>A p.P830Q | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as rs575889688, COSV100265820, COSV60048839; called by muse, varscan2
- ZNF426 | c.452G>T p.C151F | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV53471237; called by muse, mutect2
- DST | c.21384G>T p.E7128D (on ENST00000361203 / NM_001374722.1; = p.E4825D on NM_015548.5) | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- EFR3B | c.1715C>A p.A572D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2
- GATAD1 | c.763C>A p.P255T | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.254); called by muse, mutect2
- SPTA1 | c.2419G>T p.A807S | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.557); called by muse, mutect2
- TC2N | c.880G>T p.V294L | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- TCOF1 | c.987G>T p.Q329H (on ENST00000377797 / NM_001135243.1; = p.Q252H on NM_000356.4) | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- ZNF398 | c.956C>A p.A319D (on ENST00000475153 / NM_170686.3; = p.A148D on NM_020781.4) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.212); called by muse, mutect2
- SLC6A11 | c.1644C>T p.A548= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs781357408; called by muse, mutect2, varscan2
- ZNF737 | c.1260T>A p.T420= | Silent (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- AC010542.3 | c.149-12009G>T | Intron (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2
- BORCS7 | c.248+20C>A | Intron (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
